TCGA case TCGA-IB-A5SO — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c6388925-c0a1-4610-a6b9-d9d9500d88c6

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Canada; Age at index: 71 years; Vital status: Dead; Days to death: 365 days (1.0 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 71.5 years (26,129 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 365 days (1.0 years); Sites of involvement: Pancreas Head.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 12; Tumor largest dimension diameter: 3.8 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 309 days; Days to treatment end: 309 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Whipple.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Peritoneum, NOS. Age at diagnosis: 72.3 years (26,405 days); Days to diagnosis: 276 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 276 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Peritoneum, NOS; Days to recurrence: 276 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 329 days; Disease response: With Tumor.
- Days to follow up: 365 days (1.0 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IB-A5SO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 240 mg.
  Slide TCGA-IB-A5SO-01A-01-TSA: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 50; Percent normal cells: 8; Percent necrosis: 2; Percent stromal cells: 65; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 2.
- Sample TCGA-IB-A5SO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IB-A5SO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 1; Alcohol history documented: No; Diabetes diagnosis indicator: No; History chronic pancreatitis: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Cause of death: Pancreatic Cancer.
- Drug treatment: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 365 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 365 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 276 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IB-A5SO-01A-11D-A32M-01): tumor purity 0.63, ploidy 2, whole-genome doublings 0.
